Gene-level copy-number profile of tumor specimen TCGA-FD-A3N5-01A from TCGA case TCGA-FD-A3N5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 69.4 years (25,342 days).
Specimen TCGA-FD-A3N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.27eee5c0-0794-4523-bca7-a3bfabe5f74d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3N5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5f7ad49-4119-4c43-8593-f6e848fd5075

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 297; copy number 2: 11,489; copy number 3: 36,028; copy number 4: 8,938; copy number 5: 854; copy number 6: 1,318; copy number 7: 408; copy number 8: 185; copy number 9: 89; copy number 10: 12; copy number 13: 28; copy number 17: 108; copy number 23: 2; copy number 24: 22; copy number 25: 7; copy number 33: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3N5-01A-11D-A219-01): tumor purity 0.66, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 890 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–19,234,487, 353 genes, copy number 7 (broad region; genes not listed).
- chr6:19,837,370–19,894,214, 2 genes, copy number 23: ID4, AL022726.1.
- chr6:20,401,879–22,654,455, 18 genes, copy number 24 (within-gene range 2–24): E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15.
- chr6:22,085,544–22,302,826, 4 genes, copy number 24: RN7SKP240, NBAT1, AL359694.1, PRL.
- chr7:70,972–19,002,416, 302 genes, copy number 8–13 (within-gene range 3–13) (broad region; genes not listed).
- chr7:22,854,126–23,208,045, 11 genes, copy number 7: SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1.
- chr7:46,890,625–48,029,119, 15 genes, copy number 7 (within-gene range 3–7): AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3.
- chr7:53,490,148–63,154,934, 173 genes, copy number 7–33 (broad region; genes not listed).
- chr10:79,068,966–79,584,877, 12 genes, copy number 10 (within-gene range 6–10): ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P.

Autosomal genes at a single copy (total copy number 1): 297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
